Somatic mutation profile of tumor specimen TCGA-CQ-6228-01A (aliquot TCGA-CQ-6228-01A-11D-1912-08) from TCGA case TCGA-CQ-6228, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.0 years (25,942 days).
Specimen TCGA-CQ-6228-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d53b247-129d-4ad5-aae5-5877f51cf68f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6228-10A (Blood Derived Normal), aliquot TCGA-CQ-6228-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07c1ba95-12c1-4d47-b192-21386b9534ae

The open-access MAF lists 108 somatic variants for this specimen: 87 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 19, Nonsense Mutation 7, Splice Site 4, Nonstop Mutation 1, In Frame Del 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.5767+1G>A p.X1923_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | catalogued as rs756689063, CS090610, COSV99250078; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1508G>A p.G503D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV100917866; called by muse, varscan2
- AGMO | c.395A>C p.H132P | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100694650; called by muse, mutect2
- ALG10B | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100439979; called by muse, mutect2
- ALG10B | c.1169C>G p.S390* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100439982; called by muse, mutect2
- AP3B2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1279518159, COSV99916917; called by muse, mutect2
- ARHGAP35 | c.3986C>T p.P1329L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.4); catalogued as COSV101351573; called by muse, mutect2, varscan2
- ASPHD1 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100435791, COSV58104726; called by muse, mutect2, varscan2
- BCS1L | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1354673459, COSV99829185; called by muse, mutect2, varscan2
- C4orf50 | c.661C>T p.R221C (on ENST00000324058; = p.R1453C on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201256752, COSV60689457; called by muse, mutect2, varscan2
- CACFD1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52468856; called by muse, mutect2, varscan2
- CATIP | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99179624; called by muse, mutect2
- CATSPER2 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100390962; called by muse, mutect2, varscan2
- CCNQ | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as COSV99368059; called by muse, mutect2
- CFAP298-TCP10L | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs1568979891, COSV100291991, COSV55830099; called by muse, mutect2, varscan2
- CLTCL1 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595754; called by muse, mutect2, varscan2
- CSMD3 | c.8627G>A p.G2876D (on ENST00000297405 / NM_001363185.1; = p.G2707D on NM_052900.3) | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99845723; called by muse, mutect2
- CTCF | c.1945A>T p.K649* | Nonsense Mutation (SNP) | VAF 94/249 reads (38%) | catalogued as COSV99866470; called by muse, mutect2, varscan2
- DHTKD1 | c.482A>C p.E161A | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV99536854; called by muse, mutect2, varscan2
- DNAH3 | c.12219T>A p.S4073R | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99770165; called by muse, mutect2, varscan2
- DNAH5 | c.6137C>G p.A2046G | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99453391; called by muse, mutect2, varscan2
- DNAJC13 | c.2000C>G p.S667* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99607961; called by muse, mutect2, varscan2
- ELL2 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV99427848; called by muse, mutect2, varscan2
- FBN2 | c.4009A>T p.M1337L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99330213; called by muse, mutect2, varscan2
- FCRL4 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.101); catalogued as COSV99620362; called by muse, mutect2, varscan2
- GGA2 | c.1705A>G p.M569V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100564827; called by muse, mutect2, varscan2
- GOLGB1 | c.7663C>A p.L2555I | Missense Mutation (SNP) | VAF 89/158 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100511440; called by muse, mutect2, varscan2
- GPR42 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 84/105 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs368116355; called by muse, varscan2
- H3-3B | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV54665480; called by muse, mutect2, varscan2
- HRNR | c.6083G>C p.S2028T | Missense Mutation (SNP) | VAF 130/2382 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as COSV64262034; called by muse, mutect2
- HUNK | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99528880; called by muse, mutect2, varscan2
- IL7R | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100285748; called by muse, mutect2, varscan2
- IRX4 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99181413; called by muse, mutect2, varscan2
- KLHL2 | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99900270; called by muse, mutect2, varscan2
- KXD1 | c.254+1G>A p.X85_splice | Splice Site (SNP) | VAF 37/88 reads (42%) | catalogued as COSV99723718; called by muse, mutect2, varscan2
- MAGI2 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.995); catalogued as rs1348443472, COSV100836335; called by muse, mutect2, varscan2
- MCOLN2 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99394193; called by muse, mutect2, varscan2
- MED17 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 16/453 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV99316209; called by muse, mutect2
- MORC3 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101247754; called by muse, mutect2, varscan2
- MTHFD1L | c.2021C>A p.P674H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100945308; called by muse, varscan2
- NAV3 | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99894845; called by muse, mutect2, varscan2
- NEDD1 | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99901273; called by muse, mutect2, varscan2
- NPFFR2 | c.495T>G p.N165K | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441190; called by muse, mutect2, varscan2
- NRCAM | c.106+1G>A p.X36_splice | Splice Site (SNP) | VAF 29/77 reads (38%) | catalogued as rs1439940108, COSV100695342; called by muse, mutect2, varscan2
- PATJ | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417524744, COSV100334867; called by muse, mutect2, varscan2
- PAX1 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV101270375; called by muse, mutect2, varscan2
- PCDH15 | c.1978G>T p.V660F | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV57397300; called by muse, mutect2, varscan2
- PDK4 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as rs1204974606, COSV99138951; called by muse, mutect2
- PIGB | c.709A>C p.I237L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV99380664; called by muse, mutect2, varscan2
- PLA1A | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140761557; called by muse, mutect2, varscan2
- PLEKHA6 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99692658; called by muse, mutect2, varscan2
- PNISR | c.2216A>T p.D739V | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as COSV100984421; called by muse, mutect2, varscan2
- PRELID1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs750714431, COSV100293766; called by muse, mutect2, varscan2
- PRKD3 | c.1474A>T p.T492S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99306658; called by muse, mutect2, varscan2
- PRMT9 | c.2440G>A p.V814I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.123); catalogued as COSV99669783; called by muse, mutect2, varscan2
- PRPS1L1 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV101552952, COSV72649963; called by muse, mutect2, varscan2
- PTPRJ | c.1898A>C p.D633A | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV101395732; called by muse, mutect2, varscan2
- RALGAPB | c.4094A>T p.E1365V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV99485711; called by muse, mutect2, varscan2
- RBM15 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100873372; called by muse, mutect2, varscan2
- RC3H1 | c.2758C>T p.H920Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99281698; called by muse, mutect2, varscan2
- RET | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100394428; called by muse, mutect2, varscan2
- RIF1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as rs572659964, COSV54616701, COSV99691121; called by muse, mutect2, varscan2
- SEZ6 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.024); catalogued as COSV57983530; called by muse, mutect2, varscan2
- SLC41A1 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100900478; called by muse, mutect2, varscan2
- SSR4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782282879, COSV99381609; called by muse, mutect2, varscan2
- STK26 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100688864; called by muse, mutect2, varscan2
- TAF1L | c.3947A>T p.E1316V | Missense Mutation (SNP) | VAF 123/163 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV99645316; called by muse, mutect2, varscan2
- TBC1D20 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs774167151, COSV62612463; called by muse, mutect2, varscan2
- TDRD6 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1453186864, COSV100288228; called by muse, mutect2, varscan2
- TMPRSS13 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.005); catalogued as COSV101471494, COSV70625863; called by muse, mutect2, varscan2
- TP53 | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 34/42 reads (81%) | catalogued as COSV52737802, COSV52904957; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.952); catalogued as COSV99535326; called by muse, mutect2, varscan2
- TUBA3E | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as COSV99919911; called by muse, mutect2, varscan2
- UBAP2L | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99672152; called by muse, mutect2, varscan2
- UBQLN2 | c.904G>A p.G302R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV100592825; called by muse, mutect2, varscan2
- UNC13C | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99522331; called by muse, mutect2
- USP19 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100026456, COSV59730916; called by muse, mutect2, varscan2
- USP40 | c.704T>G p.L235* | Nonsense Mutation (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99297064; called by muse, mutect2, varscan2
- VNN3 | c.120A>T p.R40S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.089); catalogued as COSV99258651; called by muse, mutect2, varscan2
- ZNF384 | c.67-1G>C p.X23_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | catalogued as COSV100158848; called by muse, mutect2, varscan2
- ZNF592 | c.2221A>G p.T741A | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV100246088; called by muse, mutect2, varscan2
- ZNF646 | c.1570A>T p.I524F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100336851; called by muse, mutect2, varscan2
- IMPDH2 | c.863_868del p.K288_Y289del | In Frame Del (DEL) | VAF 12/14 reads (86%) | called by mutect2, varscan2
- KIR3DL3 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2
- LCOR | c.3478A>C p.S1160R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2
- NBAS | c.7116_*16del | Nonstop Mutation (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel
- TMPRSS3 | c.1299_1305del p.Y434Vfs*17 | Frame Shift Del (DEL) | VAF 45/111 reads (41%) | called by mutect2, pindel, varscan2
- ANGPTL6 | c.1077C>T p.A359= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs757974155, COSV99463932; called by muse, mutect2, varscan2
- CAMK1 | c.177G>A p.K59= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as COSV99844913; called by muse, mutect2, varscan2
- CELSR2 | c.3339C>T p.C1113= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs988462121, COSV54770418; called by muse, mutect2
- DRD4 | c.531G>A p.V177= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV99448860; called by muse, mutect2, varscan2
- ELN | c.2112C>T p.A704= (on ENST00000320399 / NM_001278939.1; = p.A671= on NM_000501.4) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs888990771, COSV99333058; called by muse, mutect2, varscan2
- GPRASP1 | c.3741T>C p.Y1247= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as rs758188807, COSV100851064; called by muse, mutect2, varscan2
- GRIK1 | c.2262C>A p.S754= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100517744; called by muse, mutect2, varscan2
- IQGAP3 | c.2700C>A p.I900= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV100752332; called by muse, mutect2, varscan2
- MUC5B | c.7608C>T p.S2536= | Silent (SNP) | VAF 52/144 reads (36%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1416C>T p.Y472= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs745977435, COSV99213374; called by muse, mutect2, varscan2
- NR0B1 | c.534G>A p.A178= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100973583; called by muse, mutect2, varscan2
- NR2C1 | c.1017C>T p.C339= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV100280636; called by muse, mutect2, varscan2
- NUTM2D | c.135T>C p.S45= | Silent (SNP) | VAF 20/516 reads (4%) | catalogued as COSV101097018; called by muse, mutect2
- POU6F2 | c.1122G>A p.Q374= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV101302829; called by muse, mutect2
- SNX20 | c.481C>T p.L161= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100319321; called by muse, mutect2, varscan2
- STK36 | c.691C>T p.L231= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as rs749613505, COSV99831872; called by muse, mutect2, varscan2
- TBC1D32 | c.1215A>G p.G405= | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as COSV99251093; called by muse, mutect2, varscan2
- TM6SF1 | c.822T>C p.Y274= | Silent (SNP) | VAF 140/265 reads (53%) | catalogued as COSV99362840; called by muse, mutect2, varscan2
- ZNF638 | c.2727C>G p.V909= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100039743; called by muse, mutect2, varscan2
- CEP295 | chr11:93733256 C>T | 3'Flank (SNP) | VAF 28/616 reads (5%) | called by muse, mutect2
- DUSP14 | c.1dup p.M1Nfs*? | 5'UTR (INS) | VAF 123/196 reads (63%) | called by mutect2, pindel, varscan2
